Somatic mutation profile of tumor specimen C3L-09985-02 (aliquot CPT0516630006) from CPTAC case C3L-09985, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 71.2 years (26,008 days).
Specimen C3L-09985-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abc9d15a-7e7a-42d9-b4ff-b03fdbd2bc6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09985-31 (Blood Derived Normal), aliquot CPT0516770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a001ed7c-081b-4e97-afa7-fa412119ce7c

The open-access MAF lists 91 somatic variants for this specimen: 65 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 23, Nonsense Mutation 3, Intron 2, Splice Region 1, Splice Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG2 | c.473G>T p.R158L (on ENST00000379869 / NM_001079858.3; = p.R155L on NM_005756.4) | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs147891700; called by muse, mutect2, varscan2
- AKAP7 | c.44A>T p.E15V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV63505040; called by muse, mutect2, varscan2
- AMPD2 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 63/498 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV56651430; called by muse, mutect2, varscan2
- ARHGAP39 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 254/1080 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52768235; called by muse, mutect2, varscan2
- ATG2B | c.6088G>A p.E2030K | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1255183590, COSV99952238; called by muse, mutect2, varscan2
- AURKC | c.110G>A p.R37H (on ENST00000302804 / NM_001015878.2; = p.R3H on NM_003160.3) | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV57138475; called by muse, mutect2, varscan2
- CELA2A | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs867241766; called by muse, mutect2, varscan2
- COBL | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1275939462; called by muse, mutect2, varscan2
- CYC1 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 66/777 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1274817641; called by muse, mutect2
- CYLC1 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV61411592; called by muse, mutect2, varscan2
- EGLN2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 88/658 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs765879153; called by muse, mutect2, varscan2
- FANCM | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374461604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABBR2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99409449; called by muse, varscan2
- GLI3 | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 155/536 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV67896518; called by muse, varscan2
- HNRNPM | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 97/624 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as rs775040597; called by muse, mutect2, varscan2
- HOXB3 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 210/553 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs745925398; called by muse, mutect2, varscan2
- INTS1 | c.4531C>T p.R1511C | Missense Mutation (SNP) | VAF 71/576 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs560840118, COSV104431339; called by muse, mutect2, varscan2
- ITGBL1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 96/297 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs775591671; called by muse, mutect2, varscan2
- MME | c.1441G>A p.G481S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201180963; called by muse, varscan2
- NEDD4 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 116/291 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs781648726; called by muse, mutect2, varscan2
- NLRP5 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 120/473 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs771396943, COSV66762329; called by muse, mutect2, varscan2
- QRFPR | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751553958, COSV57677217; called by muse, mutect2, varscan2
- RGPD4 | c.2447G>A p.R816H | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs535535837; called by muse, mutect2, varscan2
- SACS | c.6677C>T p.S2226F | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV101207541; called by muse, mutect2, varscan2
- SLC44A4 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752088882; called by muse, mutect2
- SLIT1 | c.3398G>A p.G1133E | Missense Mutation (SNP) | VAF 79/362 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.116); catalogued as COSV56583700; called by muse, mutect2, varscan2
- SPATA31A3 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.515); catalogued as rs984693509; called by muse, mutect2, varscan2
- SUPT3H | c.505G>A p.E169K (on ENST00000371460 / NM_181356.3; = p.E158K on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.851); catalogued as rs1232194875; called by muse, mutect2, varscan2
- SUPT6H | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 214/579 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as rs773978147; called by muse, mutect2, varscan2
- THSD7B | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 53/356 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539697788, COSV55654615; called by muse, mutect2, varscan2
- TP53 | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 146/369 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM942119, COSV52688040, COSV52961532, COSV53198425; called by muse, mutect2, varscan2
- TRIP10 | c.1315G>T p.D439Y (on ENST00000313244 / NM_001288962.2; = p.D383Y on NM_004240.4) | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770804549; called by muse, mutect2
- ZBTB38 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs975932379; called by muse, mutect2, varscan2
- ABCA13 | c.12140T>C p.L4047P | Missense Mutation (SNP) | VAF 41/586 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC4 | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ACVR1C | c.989T>C p.L330S | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRA3 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 31/456 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2
- CALN1 | c.454G>A p.D152N (on ENST00000329008 / NM_001017440.3; = p.D194N on NM_031468.4) | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL24A1 | c.1752+1G>C p.X584_splice | Splice Site (SNP) | VAF 30/199 reads (15%) | called by muse, mutect2, varscan2
- DOCK2 | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSHR | c.1840T>C p.F614L | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HDAC1 | c.516C>G p.Y172* | Nonsense Mutation (SNP) | VAF 52/237 reads (22%) | called by muse, mutect2, varscan2
- HUNK | c.1898A>G p.E633G | Missense Mutation (SNP) | VAF 82/433 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- IL10RA | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 207/485 reads (43%) | called by muse, mutect2, varscan2
- KCTD18 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 62/446 reads (14%) | called by muse, mutect2, varscan2
- LRFN3 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 88/627 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- MAP2K7 | c.639del p.I214Sfs*9 | Frame Shift Del (DEL) | VAF 130/380 reads (34%) | called by mutect2, pindel, varscan2
- MAP6 | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 41/448 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2
- MTUS2 | c.2710A>G p.K904E | Missense Mutation (SNP) | VAF 68/331 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYMK | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 57/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAV3 | c.1085C>G p.S362C | Missense Mutation (SNP) | VAF 28/494 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2
- NTN4 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA9 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 84/633 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB7 | c.1626C>A p.S542R | Missense Mutation (SNP) | VAF 238/912 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PTPRJ | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 23/418 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.341); called by muse, mutect2
- PWWP3B | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.234); called by muse, mutect2
- RBAK-RBAKDN | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 134/546 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SEC16B | c.2741G>T p.W914L | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC26A7 | c.754A>G p.K252E | Missense Mutation (SNP) | VAF 27/332 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2
- SPIDR | c.2347G>C p.V783L | Missense Mutation (SNP) | VAF 56/439 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SYN2 | c.1300C>A p.Q434K | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.989); called by muse, mutect2
- TTLL7 | c.159T>C p.V53= | Splice Region (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.4000T>C p.S1334P | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF568 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ZNF841 | c.761A>C p.E254A (on ENST00000426391 / NM_001369830.1; = p.E370A on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/305 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ANK2 | c.9045C>T p.F3015= | Silent (SNP) | VAF 79/221 reads (36%) | catalogued as rs1211416297; called by muse, mutect2, varscan2
- CENPJ | c.3171A>G p.E1057= | Silent (SNP) | VAF 80/385 reads (21%) | called by muse, mutect2, varscan2
- CPLANE1 | c.9213G>A p.T3071= | Silent (SNP) | VAF 41/247 reads (17%) | catalogued as rs572694714, COSV57069393; called by muse, mutect2, varscan2
- CRACDL | c.1242C>T p.P414= | Silent (SNP) | VAF 202/803 reads (25%) | catalogued as rs781361854, COSV67408113; called by muse, mutect2, varscan2
- CRISPLD1 | c.234A>G p.P78= | Silent (SNP) | VAF 42/308 reads (14%) | called by muse, mutect2, varscan2
- CYP11B2 | c.1117T>C p.L373= | Silent (SNP) | VAF 67/697 reads (10%) | catalogued as rs754859009; called by muse, mutect2
- DOCK4 | c.5793G>T p.L1931= | Silent (SNP) | VAF 89/582 reads (15%) | called by muse, mutect2, varscan2
- FAM83H | c.3168G>A p.A1056= | Silent (SNP) | VAF 207/1189 reads (17%) | catalogued as rs782687358; called by muse, mutect2, varscan2
- HUWE1 | c.11637A>G p.L3879= | Silent (SNP) | VAF 14/231 reads (6%) | catalogued as rs782078090; called by muse, mutect2
- IL22 | c.507G>A p.L169= | Silent (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- IMPDH2 | c.1431C>T p.T477= | Silent (SNP) | VAF 39/252 reads (15%) | catalogued as rs1279139515; called by muse, mutect2, varscan2
- INTS1 | c.2784C>T p.D928= | Silent (SNP) | VAF 74/418 reads (18%) | catalogued as rs1001323423, COSV67177369; called by muse, mutect2, varscan2
- KAT6B | c.1548T>C p.S516= | Silent (SNP) | VAF 96/461 reads (21%) | called by muse, mutect2, varscan2
- LINGO2 | c.972C>T p.R324= | Silent (SNP) | VAF 76/348 reads (22%) | catalogued as rs138682295, COSV100430124; called by muse, varscan2
- MATN4 | c.216C>T p.R72= | Silent (SNP) | VAF 81/616 reads (13%) | catalogued as COSV59215818; called by muse, mutect2, varscan2
- PACSIN3 | c.393G>A p.A131= | Silent (SNP) | VAF 246/561 reads (44%) | catalogued as rs990861514, COSV54066435; called by muse, mutect2, varscan2
- PAPPA | c.4842A>G p.Q1614= | Silent (SNP) | VAF 15/332 reads (5%) | catalogued as COSV60278755; called by muse, mutect2
- PAPSS1 | c.1641G>T p.T547= | Silent (SNP) | VAF 28/388 reads (7%) | called by muse, mutect2
- SH2B3 | c.300C>T p.A100= | Silent (SNP) | VAF 114/753 reads (15%) | called by muse, mutect2, varscan2
- TRIM60 | c.9T>C p.F3= | Silent (SNP) | VAF 37/173 reads (21%) | called by muse, mutect2, varscan2
- USH2A | c.9639G>A p.P3213= | Silent (SNP) | VAF 40/300 reads (13%) | catalogued as rs191115495; called by muse, varscan2
- XPR1 | c.1905C>T p.N635= | Silent (SNP) | VAF 62/449 reads (14%) | catalogued as rs145897362; called by muse, mutect2, varscan2
- ZFHX4 | c.9978G>A p.L3326= | Silent (SNP) | VAF 100/544 reads (18%) | catalogued as rs1329460969; called by muse, mutect2, varscan2
- CCDC40 | c.1562+2013G>A | Intron (SNP) | VAF 71/384 reads (18%) | catalogued as rs770851537; called by muse, mutect2, varscan2
- CPLANE1 | c.*4985C>T | 3'UTR (SNP) | VAF 44/167 reads (26%) | catalogued as rs768454790, COSV57050940, COSV57053745; called by muse, mutect2, varscan2
- IGSF22 | c.2096-1372C>A | Intron (SNP) | VAF 25/480 reads (5%) | catalogued as rs867467413; called by muse, mutect2
